HCMI case HCM-BROD-0226-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d73ad293-edf5-4f88-8a06-65695f5f5ff0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1980; Vital status: Alive.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 31.1 years (11,364 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IV; AJCC pathologic T: T1b; AJCC pathologic M: M1c; AJCC pathologic stage: Stage IV; Prior malignancy: yes; Prior treatment: No.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Nivolumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 2,260 days (6.2 years); Days to treatment end: 3,109 days (8.5 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 2,348 days (6.4 years); Days to treatment end: 2,348 days (6.4 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C77.4; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 37.1 years (13,533 days); Days to diagnosis: 2,169 days (5.9 years).
   Pathology details: Lymph nodes positive: 1; Lymph nodes tested: 13.

Follow-up (2 entries)
- Days to follow up: 3,109 days (8.5 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 2,724.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- NRAS mutation, nos: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 79 kg; Height: 173 cm; BMI: 26.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Melanoma.

Biospecimens (2 samples)
- Sample HCM-BROD-0226-C43-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample HCM-BROD-0226-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
